Somatic mutation profile of tumor specimen TCGA-55-8621-01A (aliquot TCGA-55-8621-01A-11D-2393-08) from TCGA case TCGA-55-8621, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 75.2 years (27,485 days).
Specimen TCGA-55-8621-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 241a7084-76d4-4e1d-83cf-b119b2d12cf4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-8621-10A (Blood Derived Normal), aliquot TCGA-55-8621-10A-01D-2393-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ca656ad9-cb41-490a-9f6e-3b308b640a94

The open-access MAF lists 54 somatic variants for this specimen: 40 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 13, Nonsense Mutation 2, Frame Shift Del 1, RNA 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACP6 | c.717G>T p.M239I | Missense Mutation (SNP) | VAF 7/199 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV100984214; called by muse, mutect2
- AGBL5 | c.1261C>G p.P421A | Missense Mutation (SNP) | VAF 33/313 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.388); catalogued as COSV100549104; called by muse, mutect2, varscan2
- ALDH1L1 | c.2286C>A p.C762* | Nonsense Mutation (SNP) | VAF 4/51 reads (8%) | catalogued as COSV99856818; called by muse, mutect2
- ANKFY1 | c.1535A>T p.Q512L | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.184); catalogued as COSV100492658; called by muse, mutect2
- ANKFY1 | c.1534C>A p.Q512K | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT tolerated (0.57); PolyPhen benign (0.085); catalogued as COSV100492659; called by muse, mutect2
- ARHGAP39 | c.3112G>A p.A1038T (on ENST00000276826 / NM_001308208.2; = p.A1069T on NM_025251.2) | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99431267; called by muse, mutect2
- ASMT | c.245C>G p.A82G | Missense Mutation (SNP) | VAF 9/232 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.137); catalogued as rs1267490714, COSV101172455, COSV67109615; called by muse, mutect2
- BTBD9 | c.1382A>G p.Y461C | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100021818; called by muse, mutect2
- CLIP4 | c.1998T>A p.D666E | Missense Mutation (SNP) | VAF 10/207 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100191901; called by muse, mutect2
- CPA2 | c.224A>G p.Q75R | Missense Mutation (SNP) | VAF 6/99 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.087); catalogued as COSV99744010; called by muse, mutect2
- CPED1 | c.877A>T p.T293S | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.397); catalogued as COSV100120709; called by muse, mutect2
- CPS1 | c.1504G>C p.D502H | Missense Mutation (SNP) | VAF 6/142 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99242998; called by muse, mutect2
- DNAJC10 | c.1489C>T p.L497F | Missense Mutation (SNP) | VAF 7/168 reads (4%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.993); catalogued as COSV99899227; called by muse, mutect2
- EXOC3L1 | c.854T>C p.V285A | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99333689; called by muse, mutect2, varscan2
- FBN2 | c.3816T>A p.Y1272* | Nonsense Mutation (SNP) | VAF 16/252 reads (6%) | catalogued as COSV99327388; called by muse, mutect2
- FBN2 | c.855del p.I286Yfs*65 | Frame Shift Del (DEL) | VAF 16/160 reads (10%) | catalogued as COSV99327380; called by mutect2, pindel
- FH | c.200A>C p.Y67S | Missense Mutation (SNP) | VAF 8/109 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100845023; called by muse, mutect2
- GABRG2 | c.1430G>A p.R477H (on ENST00000361925 / NM_001375343.1; = p.R437H on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/222 reads (7%) | SIFT tolerated (0.93); PolyPhen probably damaging (0.997); catalogued as rs587780341, COSV62720285; ClinVar: uncertain significance; called by muse, mutect2
- ID3 | c.97G>T p.A33S | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.56); PolyPhen benign (0.05); catalogued as COSV101000767; called by muse, mutect2
- KCNK2 | c.176G>T p.W59L (on ENST00000444842 / NM_001017425.3; = p.W44L on NM_014217.4) | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.082); catalogued as COSV101222143, COSV67207559; called by muse, mutect2, varscan2
- KIF23 | c.1037G>A p.R346Q | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs992414764, COSV99532324; called by muse, mutect2
- LRP1B | c.13616C>A p.P4539H | Missense Mutation (SNP) | VAF 6/103 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV101256760; called by muse, mutect2
- NFIL3 | c.1252A>C p.M418L | Missense Mutation (SNP) | VAF 7/161 reads (4%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); catalogued as COSV99906884; called by muse, mutect2
- OR1L4 | c.43C>T p.L15F | Missense Mutation (SNP) | VAF 14/288 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as COSV52339704; called by muse, mutect2
- OR6V1 | c.842C>A p.P281H | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101389367; called by muse, mutect2
- PFAS | c.1953G>T p.Q651H | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.235); catalogued as COSV100118917; called by muse, mutect2
- PI4KB | c.350G>C p.R117T (on ENST00000368873 / NM_001369623.1; = p.R129T on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/123 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV99649737; called by muse, mutect2
- PLCB1 | c.1911G>A p.M637I | Missense Mutation (SNP) | VAF 10/160 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV62053773; called by muse, mutect2
- PSG1 | c.1243+8G>T | Splice Region (SNP) | VAF 25/455 reads (5%) | catalogued as rs1324298397, COSV99739952, COSV99741025; called by muse, mutect2
- SPHKAP | c.3127G>T p.A1043S | Missense Mutation (SNP) | VAF 9/175 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.656); catalogued as COSV100764116; called by muse, mutect2
- TAF1L | c.3050T>A p.L1017H | Missense Mutation (SNP) | VAF 16/424 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99644049, COSV99644687; called by muse, mutect2
- TCF7L2 | c.821G>C p.G274A (on ENST00000355995 / NM_001367943.1; = p.G251A on NM_030756.5) | Missense Mutation (SNP) | VAF 16/222 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.119); catalogued as COSV99525793; called by muse, mutect2
- THSD7B | c.638G>T p.G213V | Missense Mutation (SNP) | VAF 13/335 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99750607; called by muse, mutect2
- TMCC3 | c.787G>T p.G263C | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99705452; called by muse, mutect2
- TMEM104 | c.1030C>T p.R344C | Missense Mutation (SNP) | VAF 43/320 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.53); catalogued as rs776808847, COSV100120679; called by muse, mutect2, varscan2
- UBR2 | c.2566-1G>A p.X856_splice | Splice Site (SNP) | VAF 10/194 reads (5%) | catalogued as COSV100867442; called by muse, mutect2
- WTIP | c.726G>T p.M242I | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV99542634; called by muse, mutect2
- ZNF160 | c.1648T>G p.S550A | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.986); catalogued as COSV100762328; called by muse, mutect2
- ADGRL2 | c.3107G>T p.W1036L (on ENST00000370717 / NM_001366005.1; = p.W1023L on NM_012302.4) | Missense Mutation (SNP) | VAF 14/407 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- TRBV19 | c.310C>A p.P104T | Missense Mutation (SNP) | VAF 13/220 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.069); called by muse, mutect2
- CFAP61 | c.2697G>C p.R899= | Silent (SNP) | VAF 10/148 reads (7%) | catalogued as COSV99844794; called by muse, mutect2
- CLEC12B | c.621A>T p.S207= | Silent (SNP) | VAF 9/160 reads (6%) | catalogued as COSV100138979; called by muse, mutect2
- DNAH8 | c.10527C>T p.G3509= | Silent (SNP) | VAF 9/132 reads (7%) | catalogued as COSV100545199, COSV100546269; called by muse, mutect2
- FER1L6 | c.2841A>G p.G947= | Silent (SNP) | VAF 10/132 reads (8%) | catalogued as COSV101205835; called by muse, mutect2
- KATNIP | c.4116G>T p.L1372= | Silent (SNP) | VAF 15/196 reads (8%) | catalogued as COSV99851072; called by muse, mutect2
- KLHL18 | c.351C>T p.F117= | Silent (SNP) | VAF 5/56 reads (9%) | catalogued as COSV99230874; called by muse, mutect2
- LYRM2 | c.27G>A p.A9= | Silent (SNP) | VAF 10/230 reads (4%) | catalogued as COSV101021314, COSV65520357; called by muse, mutect2
- MXRA8 | c.645G>C p.P215= | Silent (SNP) | VAF 3/20 reads (15%) | catalogued as COSV100491935; called by muse, mutect2
- PRKAR1A | c.645C>G p.V215= | Silent (SNP) | VAF 20/123 reads (16%) | catalogued as COSV100675168; called by muse, mutect2, varscan2
- RNF145 | c.1908A>T p.R636= (on ENST00000424310 / NM_001199383.2; = p.R664= on NM_144726.2) | Silent (SNP) | VAF 18/248 reads (7%) | catalogued as COSV99193513; called by muse, mutect2
- TAF1L | c.3048C>A p.R1016= | Silent (SNP) | VAF 16/420 reads (4%) | catalogued as COSV99644690; called by muse, mutect2
- TAF7L | c.114G>T p.G38= | Silent (SNP) | VAF 22/420 reads (5%) | catalogued as COSV100774195, COSV63300992; called by muse, mutect2
- ZNF217 | c.666C>A p.G222= | Silent (SNP) | VAF 12/220 reads (5%) | catalogued as COSV100184455; called by muse, mutect2
- GLRXP3 | n.184C>A | RNA (SNP) | VAF 22/286 reads (8%) | called by muse, mutect2
